Gene-level copy-number profile of tumor specimen TCGA-YL-A8HM-01A from TCGA case TCGA-YL-A8HM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.0 years (24,121 days).
Specimen TCGA-YL-A8HM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.367e8df6-4851-4dc7-9436-3e580b1bb71a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A8HM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e83d5a07-b778-4591-8fee-fe634a44fb70

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 2,220; copy number 2: 7,039; copy number 3: 40,948; copy number 4: 5,377; copy number 5: 3,188; copy number 6: 1,025; copy number 8: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8HM-01A-11D-A363-01): tumor purity 0.79, ploidy 2.9, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:124,664,048–124,712,732, 1 gene: ANKRD50.
- chr4:125,676,718–126,017,357, 1 gene (within-gene range 0–1): AC104664.1.
- chr4:126,064,128–126,735,523, 4 genes: LINC02379, H3P15, AC097528.1, RBM48P1.
- chr5:98,768,650–98,929,007, 6 genes (within-gene range 0–2): RGMB, RGMB-AS1, AC008522.1, CSNK1A1P3, CHD1, RNU6-402P.
- chr13:80,888,348–81,044,691, 2 genes: ARF4P4, LINC00377.
- chr13:86,909,586–86,937,108, 1 gene: LINC00430.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:122,977,026–123,152,153, 5 genes, copy number 8: AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19.

Autosomal genes at a single copy (total copy number 1): 2,220. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
